CCDI case PBBZWS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Thymic Epithelial Neoplasms; Primary site: Heart, mediastinum, and pleura.
https://portal.gdc.cancer.gov/cases/5f0a14cb-9f8c-4876-8b82-a435b7cf2fa0

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Thymic carcinoma, NOS: ICD-O-3 morphology code: 8586/3; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 17.0 years (6,221 days).

Biospecimens (3 samples)
- Sample 0DOTA6: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DOTA8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DOTAU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
